Somatic mutation profile of tumor specimen C3L-00165-05 (aliquot CPT0186400006) from CPTAC case C3L-00165, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 47.6 years (17,397 days).
Specimen C3L-00165-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 832c23d7-e9ef-4d03-844f-115a9196046b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00165-31 (Blood Derived Normal), aliquot CPT0186540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9a40b6d-690b-42fd-8735-c5eb04570ec8

The open-access MAF lists 93 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 21, Intron 7, Nonsense Mutation 4, 3'UTR 3, Frame Shift Del 3, RNA 2, Frame Shift Ins 2, Splice Region 1, 5'UTR 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 169/471 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793878, CM042503, CM941389, CM961440, COSV56543194, COSV56543241, COSV56546612; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADPGK | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61174489, COSV99076611; called by muse, mutect2, varscan2
- ANKFN1 | c.3547A>G p.I1183V (on ENST00000653862; = p.I1036V on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/345 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs375812376; called by muse, mutect2, varscan2
- AP1G2 | c.1076A>T p.D359V | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537217348; called by muse, mutect2, varscan2
- AP3B2 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.7); catalogued as COSV55613472; called by muse, mutect2, varscan2
- BAP1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 108/307 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.037); catalogued as COSV56239857, COSV56240952; called by muse, mutect2, varscan2
- BMPR2 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as CX1514011; called by muse, mutect2, varscan2
- CTNND2 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58887275, COSV58888791; called by muse, mutect2, varscan2
- FAM220A | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 120/365 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as rs1358983369; called by muse, mutect2, varscan2
- FMN2 | c.2575C>A p.P859T | Missense Mutation (SNP) | VAF 179/327 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV100146784; called by muse, mutect2, varscan2
- GOLGA3 | c.2232G>T p.Q744H | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs776188873; called by muse, mutect2, varscan2
- GPR6 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 80/375 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV51572566; called by muse, mutect2, varscan2
- GRAMD2B | c.988G>T p.G330* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99587283; called by muse, mutect2, varscan2
- HPS1 | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 121/745 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.739); catalogued as rs975447242; called by muse, mutect2, varscan2
- IPO5 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV55151805; called by muse, mutect2, varscan2
- MAP3K19 | c.2351A>G p.H784R | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1205782914; called by muse, mutect2, varscan2
- MOCOS | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.042); catalogued as COSV54341125; called by muse, mutect2, varscan2
- RRNAD1 | c.111C>T p.I37= | Splice Region (SNP) | VAF 62/692 reads (9%) | catalogued as COSV57460759; called by muse, mutect2
- STRIP2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs773569020; called by muse, mutect2, varscan2
- SULT1C2 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV52264906; called by muse, mutect2, varscan2
- TAFA1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 61/170 reads (36%) | catalogued as COSV72040780; called by muse, mutect2, varscan2
- THAP5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV50812760; called by muse, mutect2, varscan2
- TYRP1 | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs761590226; called by muse, mutect2, varscan2
- UBQLN2 | c.1400C>T p.T467I | Missense Mutation (SNP) | VAF 155/281 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1555977463, CM150282; called by muse, mutect2, varscan2
- UBQLNL | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 35/322 reads (11%) | catalogued as rs1269592529, COSV100975263; called by muse, mutect2, varscan2
- VWDE | c.2854T>G p.F952V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1413294991; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.948G>C p.R316S | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AP1G1 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRAF | c.2139C>G p.Y713* (on ENST00000288602 / NM_001374244.1; = p.Y673* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- CMTR2 | c.1093_1094insAA p.V365Efs*9 | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | called by mutect2, pindel*, varscan2
- DEPDC4 | c.700+2T>C p.X234_splice | Splice Site (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2
- DNAH3 | c.7504G>T p.V2502L | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FANCM | c.5997del p.M2000Wfs*15 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- FUBP1 | c.1784A>T p.Q595L | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- GNRHR | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- GOLGA3 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- GOLGA6L9 | c.1205_1207dup p.V402dup | In Frame Ins (INS) | VAF 72/533 reads (14%) | called by mutect2, pindel, varscan2
- HGD | c.731C>G p.T244R | Missense Mutation (SNP) | VAF 172/496 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- IGF2R | c.823T>A p.C275S | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF9B | c.2966G>A p.G989D | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LGR4 | c.1460A>T p.N487I | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRC8D | c.1116T>G p.I372M | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- MYOCD | c.1286C>A p.T429K | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.198); called by muse, mutect2
- NANOS2 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52D1 | c.592A>C p.N198H | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR5B17 | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- QRSL1 | c.424T>A p.W142R | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCYL2 | c.2528T>C p.L843P | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC46A1 | c.1357C>A p.Q453K | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SLC6A18 | c.603del p.I202Lfs*7 | Frame Shift Del (DEL) | VAF 129/437 reads (30%) | called by mutect2, pindel, varscan2
- SNRPB | c.599del p.G200Vfs*? (on ENST00000438552 / NM_198216.2; = p.G200Vfs*117 on NM_003091.4) | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- TIMELESS | c.264C>A p.N88K | Missense Mutation (SNP) | VAF 115/354 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNS3 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TSTD2 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VEGFD | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- VEZT | c.1435C>G p.Q479E | Missense Mutation (SNP) | VAF 104/381 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XRN2 | c.1733_1734dup p.A579Lfs*18 | Frame Shift Ins (INS) | VAF 44/219 reads (20%) | called by mutect2, pindel, varscan2
- ZADH2 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF25 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APLF | c.540C>T p.A180= | Silent (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2, varscan2
- B3GNT6 | c.360C>A p.L120= | Silent (SNP) | VAF 129/610 reads (21%) | called by muse, mutect2, varscan2
- C1QTNF6 | c.27G>A p.S9= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as rs749804810; called by muse, mutect2, varscan2
- COL1A1 | c.915C>T p.G305= | Silent (SNP) | VAF 148/438 reads (34%) | called by muse, mutect2, varscan2
- CORO6 | c.654G>A p.E218= | Silent (SNP) | VAF 63/155 reads (41%) | catalogued as rs1277600964; called by muse, mutect2, varscan2
- CYP2C8 | c.882A>G p.L294= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as rs1487881407; called by muse, mutect2, varscan2
- ENO4 | c.555C>T p.Y185= (on ENST00000622726; = p.Y184= on NM_001242699.2) | Silent (SNP) | VAF 19/168 reads (11%) | called by muse, mutect2, varscan2
- EPHB4 | c.930G>A p.R310= | Silent (SNP) | VAF 34/210 reads (16%) | catalogued as COSV62268424; called by muse, mutect2, varscan2
- FLG | c.10113C>T p.S3371= | Silent (SNP) | VAF 113/891 reads (13%) | catalogued as rs141599535, COSV100912231; called by muse, mutect2, varscan2
- GTF2H3 | c.507C>T p.D169= | Silent (SNP) | VAF 54/267 reads (20%) | called by muse, mutect2, varscan2
- HSD17B4 | c.2244C>T p.S748= (on ENST00000414835 / NM_001199291.3; = p.S723= on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 89/566 reads (16%) | catalogued as COSV99819669; called by muse, mutect2, varscan2
- IGHG2 | c.387C>A p.T129= | Silent (SNP) | VAF 69/316 reads (22%) | called by muse, mutect2, varscan2
- LMNB2 | c.636C>T p.C212= | Silent (SNP) | VAF 221/680 reads (33%) | called by muse, mutect2, varscan2
- MAGEE2 | c.573G>C p.G191= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- NCL | c.1002T>C p.N334= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- OR2T27 | c.351C>A p.L117= | Silent (SNP) | VAF 61/226 reads (27%) | catalogued as COSV100788422; called by muse, mutect2, varscan2
- PRRG1 | c.510A>T p.P170= | Silent (SNP) | VAF 76/156 reads (49%) | called by muse, mutect2, varscan2
- STX18 | c.552G>A p.E184= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs770827643; called by muse, mutect2
- TSEN54 | c.792G>T p.L264= | Silent (SNP) | VAF 96/273 reads (35%) | called by muse, mutect2, varscan2
- TULP3 | c.15C>T p.R5= | Silent (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- ZBTB43 | c.213T>G p.V71= | Silent (SNP) | VAF 80/220 reads (36%) | called by muse, mutect2, varscan2
- ALG2 | c.*280G>A | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- CRCP | c.-30T>A | 5'UTR (SNP) | VAF 57/166 reads (34%) | called by muse, mutect2, varscan2
- CYP11B1 | c.239+121G>A | Intron (SNP) | VAF 196/543 reads (36%) | called by muse, mutect2, varscan2
- GP6 | c.*332C>T | 3'UTR (SNP) | VAF 26/176 reads (15%) | catalogued as rs776037769; called by muse, mutect2, varscan2
- GRK4 | c.52+1197C>A | Intron (SNP) | VAF 78/482 reads (16%) | called by muse, mutect2, varscan2
- HIF3A | c.26+1302C>T | Intron (SNP) | VAF 59/206 reads (29%) | called by muse, mutect2, varscan2
- MTFR1 | c.166-4081_166-4071del | Intron (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel*, varscan2*
- RAI14 | c.36+29134A>T | Intron (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- SLC66A1L | n.243C>T | RNA (SNP) | VAF 34/203 reads (17%) | called by muse, mutect2, varscan2
- SSPOP | n.5491C>G | RNA (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- STAU1 | c.206-4879G>A | Intron (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1425C>G | 3'UTR (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- ZNF812P | n.544+1284T>C | Intron (SNP) | VAF 17/139 reads (12%) | catalogued as rs1397368997; called by muse, mutect2, varscan2
